CCDI case PBCKPZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a3ceb9ed-645f-4857-90be-7b6063e97b7e

Demographics
Sex at birth: female.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 3.9 years (1,429 days).

Biospecimens (3 samples)
- Sample 0DU9MO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU9MU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DU9NB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
